Gene-level copy-number profile of tumor specimen TARGET-40-0A4HX8-01A from TARGET case TARGET-40-0A4HX8, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 29.1 years (10,635 days).
Specimen TARGET-40-0A4HX8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.cbff4720-0723-52d3-9a6e-4fd40589b692.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-0A4HX8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 357 have no estimate.
https://portal.gdc.cancer.gov/files/4d767bbb-cf18-4337-95fa-1129f0644054

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 644; copy number 1: 11,757; copy number 2: 20,612; copy number 3: 21,565; copy number 4: 4,460; copy number 5: 1,145; copy number 6: 61; copy number 7: 22.

Homozygous deletions (total copy number 0; autosomes only): 123 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:142,023,160–142,847,432, 5 genes (within-gene range 0–1): INPP4B, RPL5P13, LSM3P4, AC139720.2, AC139720.1.
- chr7:78,392,626–78,487,028, 2 genes: AC006043.1, AC007237.1.
- chr8:39,314,591–39,522,852, 2 genes (within-gene range 0–4): ADAM5, ADAM3A.
- chr9:8,700,595–9,091,245, 6 genes: AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3.
- chr9:116,153,791–116,402,321, 4 genes (within-gene range 0–2): PAPPA, PAPPA-AS2, AL137024.1, PAPPA-AS1.
- chr11:85,852,557–86,345,943, 15 genes: AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755, AP003084.1, SETP17, HIKESHI, RN7SL225P.
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–1): RB1.
- chr13:48,328,084–51,866,232, 84 genes (broad region; genes not listed).
- chr14:79,072,132–79,074,767, 1 gene: AC026888.1.
- chr20:14,884,250–15,021,659, 3 genes: MACROD2-AS1, AL138808.1, RNU6-1159P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 22 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:87,427,214–87,892,472, 8 genes, copy number 7 (within-gene range 5–7): MIR4500HG, AL355578.1, MIR4500, SLITRK5, AL445647.2, LINC00397, AL445647.1, TET1P1.
- chr13:88,472,151–89,818,453, 14 genes, copy number 7 (within-gene range 6–7): AL355677.1, LINC00433, AL445984.2, AL445984.1, LINC00560, GRPEL2P1, AL162573.1, LINC00440, LINC01047, TRIM60P13, SP3P, LINC02336, LINC01040, LINC00353.

Autosomal genes at a single copy (total copy number 1): 9,337. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
